Gene-level copy-number profile of tumor specimen HCM-CSHL-0158-C20-01A from HCMI case HCM-CSHL-0158-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.2 years (20,877 days).
Specimen HCM-CSHL-0158-C20-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 812d44d3-1d4c-437e-bc61-ac57bb08dea6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0158-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/fd7f08c0-246d-4444-8a81-bac0224a7163

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 7,572; copy number 2: 44,776; copy number 3: 4,068; copy number 4: 1,954; copy number 5: 1; copy number 6: 4; copy number 7: 8; copy number 46: 16; copy number 48: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 31 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:133,191,039–133,571,940, 8 genes, copy number 7: CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3.
- chr14:22,226,746–22,227,254, 1 gene, copy number 5: TRAV36DV7.
- chr18:15,247,429–15,330,282, 4 genes, copy number 6: BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr20:22,684,958–22,886,068, 3 genes, copy number 46 (within-gene range 4–46): AL158175.1, KRT18P3, CYB5AP4.
- chr20:23,989,292–23,990,454, 1 gene, copy number 48: POM121L3P.
- chr20:35,954,564–36,030,700, 1 gene, copy number 48 (within-gene range 3–48): CNBD2.
- chr20:57,648,392–58,515,399, 13 genes, copy number 46 (within-gene range 3–46): PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L.

Autosomal genes at a single copy (total copy number 1): 5,228. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
